CGCI case BLGSP-71-06-00172 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c96f21de-3dd6-47ed-a796-6270c1817dd7

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: hispanic or latino; Age at index: 7 years; Vital status: Dead; Days to death: 6 days.

Diagnoses (1)
1. Burkitt-like lymphoma: ICD-O-3 morphology code: 9680/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Lip, NOS; Classification of tumor: primary; Year of diagnosis: 2016; Method of diagnosis: Incisional Biopsy; Ann Arbor pathologic stage: Stage II; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 6 days; Ann Arbor extranodal involvement: Yes; Burkitt lymphoma clinical variant: Endemic; Sites of involvement: Mandible / Maxilla.
   Pathology details: Lymph node involved site: Cervical, NOS; Tumor largest dimension diameter: 15 cm.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 0 days; Karnofsky performance status: 50; ECOG performance status: 3.
- Days to follow up: 1 day; Disease response: With Tumor.
- Days to follow up: 6 days; Disease response: With Tumor.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- Lactate Dehydrogenase 5 [Blood test normal range upper: 340].

Other clinical attributes
- Day 0: Weight: 19 kg; Height: 110 cm; BMI: 15.7.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-06-00172-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Other; Preservation method: Frozen; Days to sample procurement: 0 days; Method of sample procurement: Incisional Biopsy; Tissue collection type: Prospective.
  Slide BLGSP-71-06-00172-01A-01-S1-HE: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 10; Percent lymphocyte infiltration: 50; Percent monocyte infiltration: 30; Percent neutrophil infiltration: 5.
  Slide BLGSP-71-06-00172-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 10; Percent necrosis: 5; Percent stromal cells: 10; Percent lymphocyte infiltration: 60; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 5.
- Sample BLGSP-71-06-00172-01Z: Sample type: Tumor; Tissue type: Tumor.
  Slide BLGSP-71-06-00172-01-BCL2: Tissue microarray coordinates: E1,B3,C6.
  Slide BLGSP-71-06-00172-01-CD20: Tissue microarray coordinates: E1,B3,C6.
  Slide BLGSP-71-06-00172-01-BCL6: Tissue microarray coordinates: E1,B3,C6.
  Slide BLGSP-71-06-00172-01-HE-1: Tissue microarray coordinates: E1,B3,C6.
  Slide BLGSP-71-06-00172-01-Ki67: Tissue microarray coordinates: E1,B3,C6.
  Slide BLGSP-71-06-00172-01-CD3: Tissue microarray coordinates: E1,B3,C6.
  Slide BLGSP-71-06-00172-01-CD10: Tissue microarray coordinates: E1,B3,C6.
- Sample BLGSP-71-06-00172-99A: Sample type: Granulocytes; Tissue type: Normal; Specimen type: Granulocytes; Preservation method: Frozen; Tissue collection type: Prospective.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Days from index date to last known alive: 1; History neoadjuvant treatment: No; Tumor status: With tumor; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), atypical morphology; Extranodal site involvement: 2; Lymph nodes examined: No.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: cervical.
- Primary pathology, Extranodal involvement sites: Extranodal involvement site: Mandible; Extranodal involvement site: Maxilla.
- Stage record, Ann arbor: B symptoms present indicator: Yes.
- Tests performed: LDH level: 5; Immunophenotypic analysis method: Immunohistochemistry.
